Somatic mutation profile of tumor specimen TARGET-30-PASXGP-01A (aliquot TARGET-30-PASXGP-01A-01D) from TARGET case TARGET-30-PASXGP, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Ganglioneuroblastoma; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 2.3 years (834 days).
Specimen TARGET-30-PASXGP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68ad893b-22e5-40eb-a7b1-d788d7d6dd0d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASXGP-10A (Blood Derived Normal), aliquot TARGET-30-PASXGP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03992351-6fa7-425b-96b4-159af36d6849

The open-access MAF lists 26 somatic variants for this specimen: 17 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 7, Intron 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APAF1 | c.1879G>C p.G627R (on ENST00000551964 / NM_181861.2; = p.G616R on NM_001160.3) | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.88); catalogued as COSV59667877; called by muse, mutect2, varscan2
- BRDT | c.1145A>G p.E382G | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.08); catalogued as COSV62867074; called by muse, mutect2, varscan2
- CHML | c.1030G>C p.A344P | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59367007; called by muse, mutect2, varscan2
- DSC2 | c.2357T>G p.M786R | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV51868438; called by muse, mutect2
- FAAP24 | c.145G>C p.D49H | Missense Mutation (SNP) | VAF 53/96 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54289208; called by muse, mutect2, varscan2
- GOLGA7 | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 88/206 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV63299688; called by muse, mutect2, varscan2
- IGF2BP2 | c.934T>A p.S312T | Missense Mutation (SNP) | VAF 160/546 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.574); catalogued as COSV60490562; called by muse, mutect2, varscan2
- ISM2 | c.1619T>A p.L540H | Missense Mutation (SNP) | VAF 27/37 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV53636704; called by muse, mutect2, varscan2
- KIF2B | c.1105A>T p.N369Y | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV52134748; called by muse, mutect2, varscan2
- PTCRA | c.409C>A p.Q137K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.94); PolyPhen benign (0.025); catalogued as COSV58976656; called by muse, varscan2
- RNF123 | c.2997G>T p.L999F | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs749690153, COSV57539971; called by muse, mutect2, varscan2
- RPUSD1 | c.772C>A p.P258T | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.025); catalogued as COSV50102230; called by muse, mutect2, varscan2
- TMEM67 | c.76C>T p.L26F | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.005); catalogued as COSV60043723; called by muse, mutect2, varscan2
- TUBGCP2 | c.1703C>G p.P568R | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV53308358; called by muse, mutect2, varscan2
- VPS13A | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as rs373017066; called by mutect2, varscan2
- HLA-DRB1 | c.551T>A p.F184Y | Missense Mutation (SNP) | VAF 124/372 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.894); called by muse, mutect2
- RHOF | c.335del p.K112Sfs*24 | Frame Shift Del (DEL) | VAF 17/48 reads (35%) | called by mutect2, pindel, varscan2
- FAM50B | c.687C>T p.S229= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as rs763167959, COSV66655182; called by muse, mutect2, varscan2
- KIAA0319L | c.1119T>C p.T373= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV57849911; called by muse, mutect2, varscan2
- MKI67 | c.5967C>A p.V1989= | Silent (SNP) | VAF 120/366 reads (33%) | catalogued as COSV64076471; called by muse, mutect2, varscan2
- PHKA1 | c.3633G>A p.V1211= | Silent (SNP) | VAF 8/9 reads (89%) | catalogued as rs782098132, COSV59810958; called by muse, mutect2, varscan2
- SDK1 | c.5409G>A p.G1803= | Silent (SNP) | VAF 70/153 reads (46%) | catalogued as COSV67386077; called by muse, mutect2, varscan2
- SLC35F2 | c.723T>C p.G241= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV56185332; called by muse, mutect2, varscan2
- SMARCAL1 | c.2349C>A p.S783= | Silent (SNP) | VAF 35/84 reads (42%) | catalogued as COSV61923220; called by muse, mutect2, varscan2
- DCHS2 | n.1484T>G | RNA (SNP) | VAF 27/54 reads (50%) | catalogued as COSV59728692, COSV59737990; called by muse, mutect2, varscan2
- NBPF11 | c.-548-2765G>A | Intron (SNP) | VAF 7/24 reads (29%) | catalogued as rs1321458059; called by muse, mutect2, varscan2
